Somatic mutation profile of tumor specimen TCGA-BR-8372-01A (aliquot TCGA-BR-8372-01A-11D-2340-08) from TCGA case TCGA-BR-8372, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.9 years (23,346 days).
Specimen TCGA-BR-8372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 807c297a-725f-43f6-a870-0abe2dde7986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8372-10A (Blood Derived Normal), aliquot TCGA-BR-8372-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a47cb2d-46d0-4261-9fde-f6a74754568f

The open-access MAF lists 1,541 somatic variants for this specimen: 1,172 protein-altering or splice-affecting, 341 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 797, Silent 341, Frame Shift Del 256, Frame Shift Ins 43, Splice Site 33, Nonsense Mutation 25, Intron 10, Splice Region 7, RNA 7, In Frame Del 5, 3'Flank 4, Nonstop Mutation 3.

Variants (750 of 1,541; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.4338del p.K1446Nfs*11 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs781126037; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 38/132 reads (29%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- CNGB1 | c.2544del p.L849Cfs*15 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs760430056; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- EP300 | c.4397G>T p.W1466L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54329712, COSV54343301, COSV54343868; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 71/243 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.804del p.Y269Tfs*3 (on ENST00000642864 / NM_001111125.3; = p.Y64Tfs*3 on NM_015075.2) | Frame Shift Del (DEL) | VAF 9/12 reads (75%) | catalogued as rs886041481, CD162113; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KCNK3 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123039, CM136950, COSV100256629, COSV57192001; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 33/48 reads (69%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- RP1 | c.2700dup p.P901Tfs*2 | Frame Shift Ins (INS) | VAF 23/95 reads (24%) | catalogued as rs797044735; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs377767326, CM064283, COSV61684940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ZBTB7A | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326753, COSV59327496; called by muse, mutect2, varscan2
- AARS1 | c.2126A>G p.D709G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55746788; called by muse, mutect2, varscan2
- ABCB1 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as rs144369247; called by muse, mutect2, varscan2
- ABCB1 | c.2435G>A p.G812E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55948026; called by muse, mutect2, varscan2
- ABCC1 | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs377013600; called by muse, mutect2, varscan2
- ABCC8 | c.3857A>G p.Y1286C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435065366, COSV56848113; called by muse, mutect2, varscan2
- ABCC9 | c.722del p.K241Sfs*5 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | catalogued as rs1413468210; called by mutect2, pindel, varscan2
- ABHD4 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.668); catalogued as rs1365787403; called by muse, mutect2
- ABLIM2 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56402122; called by muse, mutect2, varscan2
- ABT1 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51290883; called by muse, mutect2, varscan2
- ACAD10 | c.2984T>C p.M995T | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1301961630, COSV58155200; called by muse, mutect2, varscan2
- ACLY | c.2236G>A p.G746R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61249952; called by muse, mutect2, varscan2
- ACOX1 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53132210; called by muse, mutect2
- ACSF3 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV58077498; called by muse, mutect2, varscan2
- ACSS1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761291852, COSV60218866; called by muse, mutect2, varscan2
- ACTN4 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53144593; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 67/109 reads (61%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs371353841; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAD2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs377587969, COSV51892960; called by muse, mutect2, varscan2
- ADAM7 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV51537349; called by muse, mutect2, varscan2
- ADAMTS1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV53169389; called by muse, mutect2, varscan2
- ADAMTS12 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1361428646, COSV61259430; called by muse, mutect2, varscan2
- ADAMTS13 | c.3313C>A p.Q1105K | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.296); catalogued as CM125029, COSV52469354; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS6 | c.2540A>G p.Q847R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as rs1208784044, COSV66858275; called by muse, mutect2
- ADCY6 | c.2309G>T p.R770L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV57166869; called by muse, mutect2, varscan2
- ADCY8 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV53902161; called by muse, mutect2, varscan2
- ADCY9 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1435229101, COSV53573389; called by muse, mutect2, varscan2
- ADGRA2 | c.267-2A>G p.X89_splice | Splice Site (SNP) | VAF 20/96 reads (21%) | catalogued as COSV59442177; called by muse, mutect2, varscan2
- ADGRF2 | c.521T>C p.V174A (on ENST00000296862 / NM_001368115.2; = p.V106A on NM_153839.7) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1350163720, COSV57287375; called by muse, mutect2, varscan2
- ADI1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772279164, COSV59376584; called by muse, mutect2, varscan2
- ADRB2 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60005320; called by muse, mutect2, varscan2
- ADRB3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.86); catalogued as COSV61461673; called by muse, mutect2
- AFAP1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61794590; called by muse, mutect2, varscan2
- AFG1L | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV64555151; called by muse, mutect2, varscan2
- AFTPH | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.036); catalogued as COSV53216891; called by muse, varscan2
- AGK | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV62594098; called by muse, mutect2, varscan2
- AGT | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as rs61762540; called by muse, mutect2, varscan2
- AHCTF1 | c.4283A>G p.E1428G (on ENST00000366508; = p.E1402G on NM_015446.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58247882; called by muse, mutect2, varscan2
- AHDC1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs372261801; called by muse, mutect2, varscan2
- AHNAK2 | c.14681C>A p.S4894Y | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV60911579; called by muse, mutect2, varscan2
- AHNAK2 | c.11011G>A p.D3671N | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.866); catalogued as rs756916033, COSV60911380; called by muse, mutect2, varscan2
- AHNAK2 | c.5933A>G p.D1978G | Missense Mutation (SNP) | VAF 120/326 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV60911587; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP8 | c.613A>G p.M205V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1251624887, COSV54101824, COSV54103209; called by muse, mutect2, varscan2
- AKR7A2 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52515997; called by muse, mutect2, varscan2
- AL592490.1 | c.1124A>G p.E375G | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.446); catalogued as COSV69425406; called by muse, mutect2, varscan2
- ALDH18A1 | c.1666A>G p.I556V | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV64662326; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALDH4A1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs568701898, COSV51893628; called by muse, mutect2, varscan2
- ALOX12B | c.1619T>C p.I540T | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174637390, COSV59872028; called by muse, mutect2
- AMER2 | c.1186T>C p.C396R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV63436797; called by muse, mutect2, varscan2
- AMER2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63436818; called by muse, mutect2, varscan2
- AMER2 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as rs1468730083, COSV63436831; called by muse, mutect2, varscan2
- AMPD3 | c.299del p.P100Rfs*60 (on ENST00000396553 / NM_001025389.2; = p.P109Rfs*60 on NM_000480.3) | Frame Shift Del (DEL) | VAF 68/233 reads (29%) | catalogued as rs751130603; called by mutect2, pindel, varscan2
- ANGPTL6 | c.899A>T p.Q300L | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV53461786; called by muse, mutect2
- ANK2 | c.3227C>A p.P1076H | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52153206; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.4309C>A p.L1437M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.141); catalogued as COSV51844027; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD26 | c.4298A>G p.E1433G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV65774200; called by muse, mutect2, varscan2
- ANKRD26 | c.3314A>G p.Q1105R | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV65774747; called by muse, mutect2
- ANKS1B | c.2100C>A p.D700E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV61342970, COSV61379683; called by muse, mutect2, varscan2
- ANO1 | c.2479A>G p.M827V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV62444626; called by muse, mutect2
- ANOS1 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as rs372801066, COSV52917583; called by muse, mutect2, varscan2
- ANTXR1 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.884); catalogued as rs1028687684, COSV100363267; called by muse, mutect2
- AP3M1 | c.1037T>A p.I346N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53008078; called by muse, mutect2, varscan2
- AP4B1 | c.937A>G p.S313G | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV56724100; called by muse, mutect2
- AP4E1 | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV55916069; called by muse, mutect2, varscan2
- APBA2 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67104457; called by muse, mutect2, varscan2
- APBA2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV67104459; called by muse, mutect2, varscan2
- APLP1 | c.1904A>G p.Q635R (on ENST00000221891 / NM_001024807.3; = p.Q634R on NM_005166.4) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55702480; called by muse, mutect2, varscan2
- AQP1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV61266372; called by muse, mutect2, varscan2
- AR | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.102); catalogued as rs1213709903, COSV65954613; called by muse, mutect2, varscan2
- ARC | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs1266406700, COSV63078268; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 24/83 reads (29%) | catalogued as rs774148781; called by mutect2, varscan2
- ARFGEF3 | c.4625A>C p.E1542A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52454032; called by muse, mutect2
- ARHGAP11B | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV70288329; called by muse, mutect2, varscan2
- ARHGAP27 | c.2033G>T p.R678L (on ENST00000428638 / NM_001282290.1; = p.R337L on NM_199282.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV65357356; called by muse, mutect2, varscan2
- ARHGAP28 | c.1465G>A p.V489I (on ENST00000383472 / NM_001366230.1; = p.V330I on NM_001010000.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749070329, COSV51634680; called by muse, mutect2, varscan2
- ARHGAP32 | c.4630G>A p.A1544T (on ENST00000310343 / NM_001378025.1; = p.A1195T on NM_014715.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs756000808, COSV59844185; called by muse, mutect2, varscan2
- ARHGEF1 | c.1244T>C p.V415A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV61526982; called by muse, mutect2, varscan2
- ARHGEF10L | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.127); catalogued as COSV63417750; called by muse, mutect2, varscan2
- ARHGEF10L | c.2893G>A p.V965M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs372655907, COSV51429414; called by muse, mutect2, varscan2
- ARHGEF11 | c.2600G>A p.R867Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215526016, COSV59352982, COSV59353160; called by muse, mutect2, varscan2
- ARID1A | c.4337G>A p.R1446Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772939817, COSV61374461; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs776520069; called by mutect2, varscan2
- ARID4B | c.3215A>G p.D1072G | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99936552; called by muse, mutect2
- ARID4B | c.2951T>C p.L984P | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.521); catalogued as COSV51600954; called by muse, mutect2, varscan2
- ARID5B | c.2059A>G p.M687V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54417003; called by muse, mutect2, varscan2
- ARMC6 | c.1061T>C p.I354T (on ENST00000392336; = p.I329T on NM_033415.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54180996; called by muse, mutect2
- ARMC9 | c.622+2T>C p.X208_splice | Splice Site (SNP) | VAF 18/71 reads (25%) | catalogued as COSV63020107; called by muse, mutect2, varscan2
- ARNT | c.1783del p.R595Gfs*11 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as COSV62230627; called by mutect2, pindel, varscan2
- ARNT2 | c.866G>T p.W289L | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57583169; called by muse, mutect2, varscan2
- ASB11 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60354753; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs778526424; called by pindel, varscan2
- ATG2A | c.1972C>A p.P658T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs779434641, COSV65966223; called by muse, mutect2, varscan2
- ATL2 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV60051067; called by muse, mutect2, varscan2
- ATN1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as COSV63110595; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP13A3 | c.1922T>C p.V641A | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55462863; called by muse, mutect2, varscan2
- ATP6AP1 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63895456, COSV63896057; called by muse, mutect2, varscan2
- ATP6V1G3 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as rs745394093, COSV55278866; called by muse, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | catalogued as rs1288664341; called by pindel, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs771612620; called by pindel, varscan2
- AVPR2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as rs782297695, COSV61685980; called by muse, mutect2, varscan2
- AXDND1 | c.871T>C p.Y291H | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62641051; called by muse, mutect2, varscan2
- AXL | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.892); catalogued as COSV56565852; called by muse, mutect2
- B3GNT6 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV62828023; called by muse, mutect2
- BAIAP3 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs750294066, COSV50103794; called by muse, mutect2, varscan2
- BAK1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.817); catalogued as COSV62349421; called by muse, varscan2
- BAZ2B | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV54275171; called by muse, mutect2, varscan2
- BBS12 | c.1313A>G p.N438S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV58561680; called by muse, mutect2, varscan2
- BCL7C | c.652T>C p.*218Rext*? | Nonstop Mutation (SNP) | VAF 81/207 reads (39%) | catalogued as COSV53063104; called by muse, mutect2, varscan2
- BCLAF1 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.959); catalogued as rs1478604293, COSV62141279; called by muse, mutect2, varscan2
- BCORL1 | c.4772T>C p.M1591T | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV54392854; called by muse, mutect2, varscan2
- BFSP2 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56587757; called by muse, mutect2, varscan2
- BMS1 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65733431; called by muse, varscan2
- BMS1 | c.2816G>T p.R939L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65733011, COSV65733435; called by muse, mutect2, varscan2
- BRD3 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57702384; called by muse, mutect2, varscan2
- BRWD1 | c.5462A>T p.D1821V | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV60894147; called by muse, mutect2, varscan2
- BRWD3 | c.2522T>C p.V841A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV64745890; called by muse, mutect2
- BTBD16 | c.563T>G p.I188S | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV53261821; called by muse, mutect2
- BTN3A1 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99176392; called by muse, mutect2, varscan2
- BTRC | c.1361G>A p.S454N (on ENST00000370187 / NM_033637.4; = p.S418N on NM_003939.5) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV64579142; called by muse, mutect2, varscan2
- BTRC | c.1780dup p.R594Pfs*27 (on ENST00000370187 / NM_033637.4; = p.R558Pfs*27 on NM_003939.5) | Frame Shift Ins (INS) | VAF 35/103 reads (34%) | catalogued as rs774921343; called by mutect2, varscan2
- BUD23 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200392309, COSV56094574; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs751388819; called by mutect2, varscan2
- C10orf90 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs756132520, COSV52952082; called by muse, mutect2, varscan2
- C11orf52 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV53714469; called by muse, mutect2, varscan2
- C14orf93 | c.98del p.T33Kfs*16 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | catalogued as COSV100136658; called by mutect2, pindel, varscan2
- C16orf71 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV54787651; called by muse, mutect2, varscan2
- C2orf78 | c.1884G>A p.M628I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs747612140, COSV68516968; called by muse, mutect2, varscan2
- C5orf22 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57597942; called by muse, mutect2, varscan2
- CA14 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV64257352; called by muse, mutect2, varscan2
- CA2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs765669662, COSV53406184; called by muse, mutect2, varscan2
- CAAP1 | c.986T>G p.V329G | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as COSV61700495; called by muse, mutect2, varscan2
- CABIN1 | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.223); catalogued as rs1043860856, COSV54079852; called by muse, mutect2, varscan2
- CACNA1B | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757636040, COSV53120239; called by muse, mutect2
- CACNA1B | c.4265A>C p.Q1422P | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53120252; called by muse, varscan2
- CACNA1I | c.4580C>A p.T1527N | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60804141; called by muse, mutect2, varscan2
- CACNG4 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200886756, COSV50924520; called by muse, mutect2, varscan2
- CAD | c.3997C>T p.R1333W | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1396370687, COSV53025064; called by muse, mutect2, varscan2
- CAMK1D | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as rs765682396, COSV66606122; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAPN2 | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54335295; called by muse, mutect2, varscan2
- CASC3 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV52866884; called by muse, mutect2, varscan2
- CASKIN1 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58871129; called by muse, mutect2, varscan2
- CASP3 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1217567390, COSV57724847; called by muse, mutect2, varscan2
- CASZ1 | c.2431A>G p.T811A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV59734012; called by muse, mutect2, varscan2
- CATSPERB | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56424230; called by muse, mutect2, varscan2
- CATSPERD | c.2303C>T p.T768M | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as rs137867416, COSV58464784; called by muse, mutect2, varscan2
- CBLC | c.1154C>T p.T385I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV54321912; called by muse, mutect2
- CC2D1B | c.1956-2A>G p.X652_splice | Splice Site (SNP) | VAF 24/155 reads (15%) | catalogued as COSV52559531; called by muse, mutect2, varscan2
- CCAR2 | c.1249dup p.R417Pfs*49 | Frame Shift Ins (INS) | VAF 34/170 reads (20%) | catalogued as rs756536005; called by mutect2, varscan2
- CCAR2 | c.2521+1G>A p.X841_splice | Splice Site (SNP) | VAF 19/109 reads (17%) | catalogued as COSV52383708; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC87 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV59578682; called by muse, mutect2, varscan2
- CCKAR | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55160691; called by muse, mutect2, varscan2
- CD14 | c.18C>G p.C6W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57370447; called by muse, mutect2, varscan2
- CD1A | c.483C>A p.F161L | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56860983; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs781937995, COSV99163893; called by mutect2, varscan2
- CDC16 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs779267341, COSV52958938; called by muse, mutect2, varscan2
- CDCA7L | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 39/127 reads (31%) | catalogued as COSV60948268; called by muse, mutect2, varscan2
- CDH10 | c.2309C>G p.P770R | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52575708, COSV52585316; called by muse, mutect2, varscan2
- CDH10 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs944908249, COSV52575713; called by muse, mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CDH6 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as COSV54066913, COSV54076006; called by muse, mutect2, varscan2
- CDK10 | c.367G>A p.D123N (on ENST00000353379 / NM_052988.5; = p.D52N on NM_052987.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57046334; called by muse, mutect2, varscan2
- CDON | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.186); catalogued as COSV54996372; called by muse, mutect2, varscan2
- CDYL2 | c.354del p.Y120Ifs*27 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as COSV101629564; called by mutect2, pindel, varscan2
- CELSR3 | c.4388C>T p.P1463L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs1342058624, COSV50844299; called by muse, mutect2
- CEMIP | c.3815T>C p.I1272T | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1228135085, COSV54990018; called by muse, mutect2, varscan2
- CEMIP2 | c.3628T>C p.Y1210H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV65486299, COSV65488955; called by muse, mutect2, varscan2
- CEP104 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs148927222; called by muse, mutect2, varscan2
- CEP83 | c.1260A>T p.Q420H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.14); catalogued as COSV60407510; called by muse, mutect2, varscan2
- CERS3 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs142269983; called by muse, mutect2, varscan2
- CERT1 | c.1142C>T p.A381V (on ENST00000405807 / NM_001130105.1; = p.A253V on NM_005713.3) | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV54656976; called by muse, mutect2, varscan2
- CFAP157 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58852460; called by muse, mutect2, varscan2
- CFAP206 | c.1404C>A p.D468E | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51533187; called by muse, mutect2, varscan2
- CFAP61 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs370904490; called by muse, mutect2, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP74 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV54566131; called by muse, mutect2, varscan2
- CFAP74 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV54566139; called by muse, mutect2, varscan2
- CFAP94 | c.751C>G p.R251G (on ENST00000320267 / NM_001352064.2; = p.R257G on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57230984; called by muse, mutect2, varscan2
- CFDP1 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52208237; called by muse, mutect2, varscan2
- CGA | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV63644248; called by muse, varscan2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs753250273; called by mutect2, pindel, varscan2
- CHRNA3 | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV58774549; called by muse, mutect2, varscan2
- CHRNE | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53417343; called by muse, mutect2, varscan2
- CHST2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV58885099; called by muse, mutect2, varscan2
- CHST5 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60338218; called by muse, mutect2, varscan2
- CHST6 | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59999776; called by muse, mutect2, varscan2
- CHSY3 | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV59275049; called by muse, mutect2, varscan2
- CIBAR1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs201718859, COSV63896699; called by muse, mutect2, varscan2
- CIITA | c.1133T>C p.L378P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV60855494; called by muse, mutect2, varscan2
- CIPC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.233); catalogued as COSV62376804; called by muse, mutect2, varscan2
- CLK3 | c.869G>A p.G290D (on ENST00000395066 / NM_001130028.1; = p.G142D on NM_003992.4) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61412028; called by muse, mutect2
- CLPS | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs780396671, COSV52565739; called by muse, mutect2, varscan2
- CNGA2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs764689669, COSV61702940; called by muse, mutect2, varscan2
- CNNM4 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs769185337, COSV65660393, COSV65661394; called by muse, mutect2, varscan2
- CNOT1 | c.3319T>G p.S1107A | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55314680; called by muse, mutect2, varscan2
- CNOT9 | c.79A>G p.N27D | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV55299494; called by muse, mutect2, varscan2
- CNTLN | c.2452C>T p.R818* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as rs754809834, COSV52072643; called by muse, mutect2, varscan2
- CNTLN | c.4175del p.K1392Rfs*3 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs747411468; called by mutect2, pindel, varscan2
- COG4 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1327159277, COSV60421833; called by muse, mutect2, varscan2
- COG8 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54742077; called by muse, mutect2, varscan2
- COL11A1 | c.5089A>G p.T1697A | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62177763; called by muse, mutect2, varscan2
- COL1A1 | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770826227, COSV56803425; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 14/45 reads (31%) | catalogued as rs760493024; called by mutect2, varscan2
- COL4A1 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs199961869, COSV65423340; called by muse, mutect2, varscan2
- COL5A1 | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65666389; called by muse, mutect2, varscan2
- COMMD4 | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.173); catalogued as COSV51190266; called by muse, mutect2, varscan2
- COPB1 | c.1455+2T>C p.X485_splice | Splice Site (SNP) | VAF 29/104 reads (28%) | catalogued as COSV51447517; called by muse, mutect2, varscan2
- CORO7 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1173808355, COSV52028979; called by muse, mutect2, varscan2
- CPSF1 | c.1279A>G p.T427A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV62939523; called by muse, mutect2, varscan2
- CPXCR1 | c.608A>T p.H203L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52161670; called by muse, mutect2, varscan2
- CRABP1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs1289593499, COSV55115513; called by muse, mutect2, varscan2
- CROCC | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs761562886, COSV65011124; called by muse, varscan2
- CSGALNACT1 | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59975609; called by muse, mutect2, varscan2
- CSMD1 | c.7477G>T p.A2493S (on ENST00000520002; = p.A2492S on NM_033225.6) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV59301849; called by muse, mutect2, varscan2
- CSMD1 | c.2230G>A p.G744R (on ENST00000520002; = p.G743R on NM_033225.6) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs991206384, COSV59277559; called by muse, mutect2, varscan2
- CSTF1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs762176502, COSV53858360; called by muse, mutect2, varscan2
- CTIF | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV56481609; called by muse, mutect2
- CTR9 | c.1204A>G p.K402E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV63728191; called by muse, mutect2, varscan2
- CUX1 | c.1090A>G p.M364V (on ENST00000292535 / NM_181552.4; = p.M375V on NM_001913.5) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV52895077; called by muse, mutect2
- CXCR1 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV55281431; called by muse, mutect2, varscan2
- CYP1A2 | c.1469A>G p.D490G | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV59659379; called by muse, mutect2
- CYP2B6 | c.172-1G>A p.X58_splice | Splice Site (SNP) | VAF 31/73 reads (42%) | catalogued as rs1389789429, COSV100137853; called by muse, varscan2
- CYP4F3 | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV55408274; called by muse, mutect2, varscan2
- DAB1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59725163; called by muse, mutect2, varscan2
- DAB2 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201522659; called by muse, mutect2, varscan2
- DCAF11 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs1412587360, COSV58108240, COSV58108659; called by muse, mutect2, varscan2
- DCAF12L1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs370562344, COSV64421438; called by muse, mutect2, varscan2
- DCDC1 | c.4840A>G p.T1614A (on ENST00000597505 / NM_001367979.1; = p.T721A on NM_020869.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100360844; called by muse, mutect2, varscan2
- DCLK1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV55179278; called by muse, mutect2, varscan2
- DCSTAMP | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV52576028, COSV52577809; called by muse, mutect2, varscan2
- DDRGK1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770146758, COSV63226666; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX58 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV65882763; called by muse, mutect2, varscan2
- DENND4A | c.4153T>G p.S1385A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.294); catalogued as COSV71265512; called by muse, mutect2, varscan2
- DGKE | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52349306; called by muse, mutect2, varscan2
- DHX30 | c.1264C>T p.R422W (on ENST00000445061 / NM_138615.3; = p.R383W on NM_014966.3) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs748601991, COSV53136446; called by muse, mutect2, varscan2
- DHX9 | c.2352-2A>C p.X784_splice | Splice Site (SNP) | VAF 66/180 reads (37%) | catalogued as COSV62358835; called by muse, mutect2, varscan2
- DIO3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63773286; called by muse, varscan2
- DIS3L2 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as rs764432869, COSV56051188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs916356077, COSV53828791; called by muse, mutect2
- DLK1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.964); catalogued as rs1238174560, COSV57991087; called by muse, mutect2, varscan2
- DMKN | c.1364dup p.V456Sfs*61 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | catalogued as rs758253239; called by mutect2, pindel, varscan2
- DMRT3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs749745516, COSV51903293, COSV51903429, COSV51906082; called by muse, mutect2, varscan2
- DNA2 | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866149439, COSV64427282, COSV64428041; called by muse, varscan2
- DNAH1 | c.12409A>G p.I4137V | Missense Mutation (SNP) | VAF 166/432 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV56232444; called by muse, mutect2, varscan2
- DNLZ | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs548961606, COSV52517273, COSV99395979; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52397321; called by muse, mutect2, varscan2
- DOCK6 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV53912905; called by muse, mutect2, varscan2
- DOCK7 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373543179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK3 | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.417); catalogued as COSV57251542; called by muse, mutect2, varscan2
- DOLK | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759025031, COSV58280372; called by muse, mutect2, varscan2
- DPP6 | c.2113C>T p.R705C (on ENST00000377770 / NM_001364500.2; = p.R643C on NM_001936.5) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766025829, COSV59604879; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 62/196 reads (32%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DRG2 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56728013; called by muse, mutect2, varscan2
- DSG1 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.098); catalogued as rs371165240; called by muse, mutect2, varscan2
- DSTYK | c.1783A>G p.S595G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV65685937; called by muse, mutect2, varscan2
- DYRK3 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65605734; called by muse, mutect2
- EARS2 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV71942790; called by muse, mutect2, varscan2
- EDEM1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770826919, COSV56581380; called by muse, mutect2, varscan2
- EDNRB | c.311C>T p.A104V (on ENST00000377211 / NM_001201397.1; = p.A14V on NM_000115.5) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as rs548023225, COSV57519093; called by muse, mutect2, varscan2
- EFL1 | c.2536T>C p.S846P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV51604288; called by muse, mutect2, varscan2
- EGR3 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV57833226; called by muse, mutect2, varscan2
- EHBP1L1 | c.1812A>G p.I604M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58572096; called by muse, mutect2, varscan2
- EIF4G3 | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51678396; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 110/166 reads (66%) | catalogued as rs766700925; called by mutect2, varscan2
- ELOA2 | c.1285A>T p.K429* | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | catalogued as COSV55296327; called by muse, mutect2, varscan2
- EMC1 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1165994376, COSV64345508; called by muse, mutect2, varscan2
- EMG1 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54641449; called by muse, mutect2, varscan2
- ENAH | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious, low confidence (0.01); catalogued as rs372263028; called by muse, mutect2, varscan2
- ENO3 | c.1235+2T>A p.X412_splice | Splice Site (SNP) | VAF 47/169 reads (28%) | catalogued as COSV52776713; called by muse, mutect2, varscan2
- EPDR1 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52259135, COSV52261159; called by muse, mutect2, varscan2
- EPHA1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs140233341; called by muse, mutect2, varscan2
- EPHA3 | c.2538del p.M847Wfs*10 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs1317589623; called by mutect2, pindel, varscan2
- EPHA5 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV56638005, COSV56662927; called by muse, mutect2, varscan2
- EPHB1 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as rs779665397, COSV67657185; called by muse, mutect2, varscan2
- EPPK1 | c.4259G>A p.R1420H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs372980887; called by muse, mutect2
- ERBB4 | c.3353A>G p.H1118R | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61476312; called by muse, mutect2, varscan2
- ERCC6L | c.2898T>A p.N966K | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57819975; called by muse, mutect2, varscan2
- ERGIC2 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV64111566; called by muse, mutect2, varscan2
- ERICH1 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs770371219, COSV50637549; called by muse, mutect2, varscan2
- ERLIN2 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52419987; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as rs775950025; called by mutect2, varscan2
- ETFB | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as COSV58535575; called by muse, mutect2, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | catalogued as COSV54136078; called by mutect2, pindel, varscan2
- EXTL1 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV65337286; called by muse, mutect2, varscan2
- EXTL3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs769181445, COSV55037016, COSV55037485; called by muse, mutect2, varscan2
- F13B | c.94A>T p.N32Y | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66373067; called by muse, mutect2, varscan2
- FAM110B | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs200606254; called by muse, mutect2
- FAM124A | c.704A>G p.D235G (on ENST00000322475 / NM_001242312.2; = p.D271G on NM_145019.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV54475171; called by muse, mutect2, varscan2
- FAM155B | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779130281, COSV52935637; called by muse, mutect2
- FAM83G | c.2446G>T p.A816S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.083); catalogued as COSV58756582; called by muse, mutect2, varscan2
- FANCA | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as COSV66881020; called by muse, mutect2, varscan2
- FANCD2 | c.809T>C p.L270S | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55035514; called by muse, mutect2
- FASN | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs781366271, COSV60752194; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT2 | c.2759A>G p.D920G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55816448; called by muse, mutect2, varscan2
- FBN3 | c.2978T>C p.F993S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54456865; called by muse, mutect2, varscan2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs772353703; called by mutect2, pindel, varscan2
- FBXO11 | c.2738A>G p.Y913C (on ENST00000403359 / NM_001190274.2; = p.Y829C on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52276616; called by muse, mutect2, varscan2
- FBXO21 | c.1400C>T p.A467V (on ENST00000330622 / NM_033624.3; = p.A460V on NM_015002.3) | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs769844730, COSV57972154; called by muse, mutect2, varscan2
- FCGBP | c.10282G>A p.G3428R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs745724423; called by muse, mutect2, varscan2
- FCRLB | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61059334; called by muse, mutect2, varscan2
- FER1L6 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67549028; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGF20 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51661087; called by muse, mutect2, varscan2
- FGF9 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV66644307; called by muse, mutect2, varscan2
- FGFR1 | c.842G>A p.S281N (on ENST00000447712 / NM_023110.3; = p.S279N on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV58331207; called by muse, mutect2, varscan2
- FILIP1L | c.1718C>T p.A573V (on ENST00000354552 / NM_182909.3; = p.A333V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs774617850, COSV58766718; called by muse, mutect2, varscan2
- FLNC | c.7877G>A p.S2626N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs2639142, COSV99972558; ClinVar: uncertain significance; called by mutect2, varscan2
- FMO4 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV63000786; called by muse, mutect2, varscan2
- FNDC5 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV100992489; called by muse, mutect2
- FOSB | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62278512; called by muse, mutect2, varscan2
- FOXD2 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58303818; called by muse, mutect2, varscan2
- FOXF1 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52285488; called by muse, mutect2, varscan2
- FOXI2 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV59094267; called by muse, mutect2, varscan2
- FOXRED1 | c.810+2T>C p.X270_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55005764; called by muse, mutect2, varscan2
- FREM1 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs563740380, COSV66520934; called by muse, mutect2, varscan2
- FRMPD1 | c.2537A>G p.Y846C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs766415968, COSV66699729; called by muse, mutect2, varscan2
- FRMPD2 | c.567+2T>C p.X189_splice | Splice Site (SNP) | VAF 35/97 reads (36%) | catalogued as COSV59716603; called by muse, mutect2, varscan2
- FTH1 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV56444910; called by muse, mutect2, varscan2
- FURIN | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs749858583, COSV51575620; called by muse, mutect2, varscan2
- GAL3ST4 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs200571320, COSV52783674; called by muse, mutect2, varscan2
- GALNT17 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1315864683, COSV61149103, COSV61154984; called by muse, varscan2
- GALR1 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.444); catalogued as COSV55316521; called by muse, mutect2, varscan2
- GAN | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV73720815; called by muse, mutect2, varscan2
- GASK1B | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV56705803; called by muse, mutect2, varscan2
- GDI1 | c.1045T>C p.Y349H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV50130879; called by muse, mutect2, varscan2
- GDPGP1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs183567818, COSV61575695; called by muse, mutect2, varscan2
- GET4 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56212003; called by muse, mutect2, varscan2
- GFM2 | c.1538A>G p.Q513R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV57190185; called by muse, mutect2
- GFOD2 | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV52057417; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs750227570; called by mutect2, varscan2
- GLMP | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs199574266, COSV55294001; called by muse, mutect2, varscan2
- GLUD2 | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV60151576; called by muse, mutect2, varscan2
- GOT1L1 | c.870del p.N291Tfs*24 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as rs768946390; called by mutect2, pindel, varscan2
- GP1BA | c.1480dup p.T494Nfs*4 | Frame Shift Ins (INS) | VAF 32/84 reads (38%) | catalogued as rs759573909; called by mutect2, varscan2
- GPATCH3 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64651840; called by muse, mutect2, varscan2
- GPC6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760150200, COSV65500771, COSV65503817; called by muse, mutect2, varscan2
- GPKOW | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1557090461; called by muse, mutect2
- GPR139 | c.730del p.R244Afs*4 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as COSV58505701; called by mutect2, varscan2
- GPR179 | c.6218A>G p.E2073G (on ENST00000621958; = p.E2072G on NM_001004334.4) | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs761039469; called by muse, mutect2, varscan2
- GPR18 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374416624; called by muse, mutect2, varscan2
- GPR37 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58256147; called by muse, mutect2, varscan2
- GPR37 | c.541del p.Y181Tfs*65 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | catalogued as COSV58259789; called by mutect2, pindel, varscan2
- GPR78 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.295); catalogued as rs1302542029, COSV66762746; called by muse, mutect2, varscan2
- GPRASP2 | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59990727; called by muse, mutect2, varscan2
- GPS1 | c.1265A>G p.K422R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV57648251; called by muse, mutect2, varscan2
- GPSM2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51441836; called by muse, mutect2, varscan2
- GRAMD2B | c.750A>T p.E250D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV53506736; called by muse, mutect2, varscan2
- GRID2 | c.2927G>T p.R976M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV56188378; called by muse, mutect2, varscan2
- GRIK2 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59724677; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2C | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV53111039; called by muse, mutect2, varscan2
- GRIN3A | c.914A>G p.Q305R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62452122; called by muse, mutect2, varscan2
- GRM1 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV51121607; called by muse, mutect2, varscan2
- GRM1 | c.1043G>T p.R348M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV51121694; called by muse, mutect2, varscan2
- GRM1 | c.2954C>T p.A985V | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV51121777; called by muse, mutect2
- GRM1 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV51121869; called by muse, mutect2, varscan2
- GRM3 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1227263804, COSV64469309; called by muse, mutect2, varscan2
- GRM3 | c.2545A>G p.T849A | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV64469317; called by muse, mutect2, varscan2
- GRXCR2 | c.464A>C p.E155A | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV65060915; called by muse, varscan2
- GRXCR2 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV65060920; called by muse, varscan2
- GSTM5 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV56657191, COSV56658157; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1729T>C p.S577P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs782289207, COSV100736483; called by muse, mutect2, varscan2
- GTF3C1 | c.5282A>C p.E1761A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62239949; called by muse, mutect2, varscan2
- GTF3C1 | c.3727A>G p.R1243G | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV62239954; called by muse, mutect2, varscan2
- GTPBP1 | c.1250T>C p.L417P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as COSV53283888; called by muse, mutect2, varscan2
- GTPBP3 | c.90del p.G31Afs*9 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as COSV99344300; called by mutect2, pindel, varscan2
- GUCY2C | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV53788494; called by muse, mutect2, varscan2
- H1-4 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.067); catalogued as COSV56800404; called by muse, mutect2, varscan2
- H2BC11 | c.379T>C p.*127Qext*? | Nonstop Mutation (SNP) | VAF 36/87 reads (41%) | catalogued as COSV60361894; called by muse, mutect2, varscan2
- H2BC6 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV61590886; called by muse, varscan2
- H4C5 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63486415; called by muse, mutect2, varscan2
- HDAC4 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV61862413; called by muse, mutect2, varscan2
- HDAC7 | c.1640G>A p.R547H (on ENST00000427332; = p.R586H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777217285, COSV50330955; called by mutect2, varscan2
- HECTD4 | c.7526A>G p.K2509R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV66389209; called by muse, mutect2, varscan2
- HERC1 | c.6814_6816del p.E2272del | In Frame Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs1182572665; called by pindel, varscan2
- HERC1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1282706501, COSV71246896; called by muse, mutect2
- HERC2 | c.10712C>T p.A3571V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs151205330; called by muse, mutect2, varscan2
- HERC2 | c.6137C>T p.P2046L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs141981089, COSV99875456; called by muse, mutect2, varscan2
- HERC5 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52038370; called by muse, mutect2, varscan2
- HFE | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs915273578, COSV58512827; called by muse, mutect2, varscan2
- HIC2 | c.1009_1011del p.K337del | In Frame Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs1568944191; called by pindel, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 38/191 reads (20%) | catalogued as rs199474609; called by mutect2, pindel, varscan2
- HNF4A | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs376906221; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXB4 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV60178150; called by muse, mutect2, varscan2
- HOXC13 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV54498402; called by muse, mutect2, varscan2
- HPS4 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs797045615, COSV61102959; ClinVar: uncertain significance; called by muse, varscan2
- HRC | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs1310733497, COSV53255759; called by muse, mutect2, varscan2
- HRH3 | c.1184A>C p.E395A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58048062; called by muse, mutect2, varscan2
- HRH3 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs770496105, COSV58048077; called by muse, mutect2, varscan2
- HRH4 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV99907756; called by muse, mutect2
- HS6ST3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV65005475; called by muse, mutect2, varscan2
- HS6ST3 | c.1000A>C p.N334H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV65005481; called by muse, mutect2, varscan2
- HTR1B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1320155895, COSV64051290; called by muse, mutect2, varscan2
- HYDIN | c.11207A>G p.Q3736R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV66638142; called by muse, mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs1202143274; called by mutect2, varscan2
- IFT140 | c.1469A>G p.H490R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs537123341, COSV68487038; called by muse, mutect2, varscan2
- IFTAP | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770886815, COSV57557021; called by muse, mutect2, varscan2
- IGHG1 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1241201658; called by muse, mutect2, varscan2
- IGHM | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs1445296995; called by muse, mutect2, varscan2
- IKZF2 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.603); catalogued as rs372734153; called by muse, mutect2, varscan2
- IL16 | c.3652G>A p.A1218T (on ENST00000302987 / NM_172217.5; = p.A517T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV57154343; called by muse, mutect2, varscan2
- IL17B | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs374213956; called by muse, mutect2, varscan2
- IL17REL | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs754650566, COSV58007963; called by muse, mutect2, varscan2
- ILF3 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51555536; called by muse, mutect2, varscan2
- ILRUN | c.572T>C p.L191P (on ENST00000374023 / NM_024294.4; = p.L125P on NM_022758.6) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64989710; called by muse, mutect2, varscan2
- INPP5K | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs754509919, COSV57440510; called by muse, mutect2, varscan2
- INPP5K | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57440526; called by muse, mutect2, varscan2
- INSRR | c.707del p.G236Afs*12 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as COSV100947394; called by mutect2, pindel, varscan2
- INTS8 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 80/289 reads (28%) | catalogued as rs1372371977, COSV58249539; called by muse, mutect2, varscan2
- INTS8 | c.2954del p.K985Sfs*44 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as rs1352150703; called by mutect2, varscan2
- IREB2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867914053, COSV51921573; called by muse, mutect2, varscan2
- IRF9 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60702930; called by muse, mutect2, varscan2
- IRGC | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54983441; called by muse, mutect2, varscan2
- ITGB6 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.508); catalogued as rs144967638, COSV51792144; called by muse, mutect2, varscan2
- ITPRID2 | c.3319del p.S1107Pfs*36 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | catalogued as rs1318064731; called by mutect2, pindel, varscan2
- KAT6B | c.2753A>G p.H918R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs921651022, COSV54744670; called by muse, mutect2, varscan2
- KCNF1 | c.598T>C p.C200R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54462565; called by muse, mutect2, varscan2
- KCNF1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV54462582; called by muse, mutect2, varscan2
- KCNG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1386260978, COSV65368626; called by muse, mutect2, varscan2
- KCNK10 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV56641587; called by muse, mutect2, varscan2
- KCNK2 | c.191C>T p.T64M (on ENST00000444842 / NM_001017425.3; = p.T49M on NM_014217.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs1020025325, COSV67204439; called by muse, mutect2, varscan2
- KCNK5 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs779600138, COSV63988727; called by muse, mutect2, varscan2
- KCNMA1 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54237804; called by muse, mutect2, varscan2
- KCNQ3 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV66467035; called by muse, varscan2
- KCNT1 | c.3220G>A p.A1074T (on ENST00000488444; = p.A1100T on NM_020822.3) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769422518, COSV53698810; ClinVar: uncertain significance; called by muse, mutect2
- KCTD2 | c.261A>C p.R87S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56902677; called by muse, varscan2
- KDM2B | c.3609A>G p.P1203= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as COSV65639174; called by muse, mutect2, varscan2
- KDM2B | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV65639186; called by muse, mutect2, varscan2
- KEAP1 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50268935; called by muse, mutect2, varscan2
- KHNYN | c.1685+2T>C p.X562_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as COSV52159515; called by muse, mutect2, varscan2
- KIAA1217 | c.5743A>G p.T1915A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV56814728; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs752375544, COSV54318481; called by mutect2, pindel, varscan2
- KIAA1586 | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1031599667, COSV66056339; called by muse, mutect2, varscan2
- KIF16B | c.2560G>C p.V854L | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.066); catalogued as COSV61703810; called by muse, mutect2
- KIF4B | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70528508; called by muse, mutect2, varscan2
- KIFC3 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV65549547; called by muse, mutect2
- KLB | c.3092T>C p.L1031S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV57300859; called by muse, mutect2, varscan2
- KLHL36 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs779641007, COSV50718391; called by muse, mutect2, varscan2
- KMT2B | c.5730del p.R1911Dfs*23 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as COSV55867385; called by mutect2, pindel, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 51/163 reads (31%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KMT2D | c.7780del p.L2594Wfs*97 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs35050033; called by mutect2, pindel, varscan2
- KRT23 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV52927420; called by muse, mutect2, varscan2
- KRT3 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV58815090; called by muse, mutect2, varscan2
- KRTAP1-5 | c.190A>C p.S64R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV62624119, COSV62624318; called by muse, varscan2
- LAMA1 | c.7850C>T p.T2617M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs751200271, COSV67533423; called by muse, mutect2, varscan2
- LAMA5 | c.9370G>A p.A3124T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs377731667; called by muse, mutect2, varscan2
- LAMA5 | c.4090C>T p.R1364C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs762846297, COSV53356362; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARS2 | c.*151-2A>C | Splice Site (SNP) | VAF 34/108 reads (31%) | catalogued as COSV55526446; called by muse, mutect2, varscan2
- LATS2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs1163593629, COSV66873953; called by muse, varscan2
- LCK | c.324A>T p.E108D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV60739389; called by muse, mutect2, varscan2
- LCNL1 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56400058; called by muse, mutect2, varscan2
- LDHB | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as COSV63364494; called by muse, mutect2, varscan2
- LENG8 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs770711332, COSV58726873; called by muse, mutect2, varscan2
- LGR6 | c.2711G>A p.C904Y (on ENST00000367278 / NM_001017403.1; = p.C852Y on NM_021636.3) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV55154225; called by muse, mutect2, varscan2
- LHFPL4 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV55001492; called by muse, mutect2, varscan2
- LIMS2 | c.583G>A p.V195I (on ENST00000355119 / NM_001161403.3; = p.V219I on NM_017980.4) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs560750824, COSV55754460; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPCAT1 | c.1435T>C p.F479L | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV52036590; called by muse, mutect2, varscan2
- LRFN5 | c.1053T>A p.D351E | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV53249756; called by muse, mutect2, varscan2
- LRP1 | c.4243G>A p.A1415T | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV54506074; called by muse, mutect2
- LRRC25 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV59114907; called by muse, mutect2, varscan2
- LRRC4 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1436155405, COSV50813502; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs1557715031, COSV58440688; called by mutect2, varscan2
- LRRC61 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV56230999, COSV99784519, COSV99784586; called by muse, mutect2, varscan2
- LRRC73 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV52500085; called by muse, mutect2, varscan2
- LRRC8E | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60717414; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470dup p.R491Tfs*14 | Frame Shift Ins (INS) | VAF 31/59 reads (53%) | catalogued as rs779699744; called by mutect2, varscan2
- LRRK2 | c.6677T>C p.V2226A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54148509; called by muse, mutect2, varscan2
- LRRN4 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.076); catalogued as rs745340794, COSV66644904; called by muse, mutect2, varscan2
- LY75 | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV55103757; called by muse, mutect2
- LYAR | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV58642466, COSV58642673; called by muse, mutect2, varscan2
- LYRM4 | c.206A>C p.Q69P | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57989597, COSV57990754; called by muse, mutect2, varscan2
- MAB21L4 | c.173T>G p.I58S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV56743127; called by muse, mutect2, varscan2
- MACF1 | c.8128G>A p.A2710T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV57113904; called by muse, mutect2, varscan2
- MACO1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs113398522, COSV65475108; called by muse, mutect2, varscan2
- MAEA | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53261888; called by muse, mutect2, varscan2
- MAFF | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV58298923; called by mutect2, varscan2
- MAGEL2 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV58566435; called by muse, mutect2, varscan2
- MAN2C1 | c.1995del p.T666Pfs*14 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV99145631; called by mutect2, pindel, varscan2
- MAP1A | c.8141G>A p.R2714Q | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs764645515, COSV55807410; called by muse, mutect2, varscan2
- MAP2K3 | c.854C>T p.P285L (on ENST00000342679 / NM_145109.3; = p.P256L on NM_002756.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs371545792; called by muse, mutect2, varscan2
- MAP3K3 | c.636+1G>A p.X212_splice | Splice Site (SNP) | VAF 28/84 reads (33%) | catalogued as COSV62280187; called by muse, mutect2, varscan2
- MARCHF10 | c.335T>C p.M112T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60886174; called by muse, mutect2, varscan2
- MBD2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160707623, COSV56500562; called by muse, mutect2, varscan2
- MBTPS1 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV58570053; called by muse, mutect2, varscan2
- MC4R | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55351538; called by muse, mutect2, varscan2
- MCF2L | c.2053A>G p.M685V (on ENST00000375608; = p.M653V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV56176665; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MED12L | c.6425C>A p.P2142H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as COSV99199863; called by muse, mutect2
- MED14 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1209691565, COSV61356360; called by muse, mutect2, varscan2
- MED18 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.843); catalogued as rs374582127; called by muse, mutect2, varscan2
- MEGF10 | c.2729-1G>T p.X910_splice | Splice Site (SNP) | VAF 38/101 reads (38%) | catalogued as COSV57247350; called by muse, mutect2, varscan2
- MET | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1306081840, COSV59259124; called by muse, varscan2
- METTL7A | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV59840556; called by muse, mutect2, varscan2
- MEX3B | c.258T>C p.G86= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as COSV61663088; called by muse, mutect2, varscan2
- MFHAS1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52280849; called by muse, mutect2, varscan2
- MFSD14A | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54927223; called by muse, mutect2, varscan2
- MFSD4A | c.916T>A p.S306T | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV65656258; called by muse, mutect2, varscan2
- MFSD6 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55621824; called by muse, mutect2, varscan2
- MGST1 | c.405dup p.V136Cfs*17 | Frame Shift Ins (INS) | VAF 47/144 reads (33%) | catalogued as rs778971425; called by mutect2, varscan2
- MIA3 | c.4424A>G p.Q1475R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV60511474; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as COSV54098507; called by pindel, varscan2
- MIGA1 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66223249; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 50/134 reads (37%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIS18BP1 | c.1606A>G p.N536D | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1209514638, COSV60369858; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs749903408; called by mutect2, varscan2
- MMP11 | c.421A>C p.T141P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53155797; called by muse, mutect2, varscan2
- MMUT | c.1879C>A p.H627N | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM012792, COSV51272833; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 4/30 reads (13%) | catalogued as rs777649506, COSV53202254; called by pindel, varscan2
- MORC3 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs915327134, COSV68688044; called by muse, mutect2, varscan2
- MOS | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV61336091; called by muse, varscan2
- MPC1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs139163077; ClinVar: uncertain significance; called by muse, varscan2
- MPG | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs764172082, COSV54737408; called by muse, mutect2, varscan2
- MRGPRX1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV57106460; called by muse, mutect2, varscan2
- MRM2 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54247792; called by muse, mutect2, varscan2
- MRPL2 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs751950769, COSV52434449, COSV99432697; called by muse, mutect2, varscan2
- MRPL9 | c.203dup p.R69Pfs*13 | Frame Shift Ins (INS) | VAF 14/59 reads (24%) | catalogued as rs748801980; called by mutect2, varscan2
- MS4A2 | c.127T>G p.S43A | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV54012101; called by muse, mutect2, varscan2
- MTMR3 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1391804249, COSV60302886; called by muse, mutect2, varscan2
- MTRES1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.105); catalogued as COSV60967783; called by muse, mutect2, varscan2
- MTSS1 | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767467644, COSV52674582; called by muse, mutect2, varscan2
- MTSS2 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs775786354, COSV55380392; called by muse, mutect2, varscan2
- MTUS1 | c.1967T>C p.V656A | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1222978523, COSV50553004; called by muse, mutect2, varscan2
- MUC5B | c.14593G>A p.A4865T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs866049956, COSV71591006; called by muse, mutect2
- MYH2 | c.5540G>A p.R1847H | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs748605415, COSV55434665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH3 | c.5099G>A p.R1700Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747006068, COSV56862977; called by muse, mutect2, varscan2
- MYLIP | c.967T>C p.Y323H | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV62766549; called by muse, mutect2, varscan2
- MYO18B | c.7196T>G p.L2399R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV59129815; called by muse, mutect2, varscan2
- MYO1F | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as rs759707124, COSV57793206; called by muse, mutect2, varscan2
- MYO3B | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760427310, COSV58699107; called by muse, mutect2, varscan2
- MYO5A | c.3697A>G p.S1233G | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV62558467; called by muse, mutect2, varscan2
- MYOM1 | c.4364T>C p.V1455A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55288259; called by muse, mutect2, varscan2
- NAA25 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55703242; called by muse, mutect2, varscan2
- NAIF1 | c.318del p.P107Lfs*14 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs1394901938; called by mutect2, pindel, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NASP | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); catalogued as rs1175191174, COSV63112482; called by muse, mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as COSV100601638; called by mutect2, varscan2
- NBPF1 | c.1837C>A p.L613M | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750771615, COSV55325193; called by muse, mutect2, varscan2
- NBPF1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.908); catalogued as rs1261792604, COSV101236863; called by mutect2, varscan2
- NCSTN | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs769698945, COSV54186509; called by muse, mutect2, varscan2
- NDST1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753004555, COSV55785859; called by muse, mutect2, varscan2
- NDST2 | c.1753T>C p.C585R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55213520; called by muse, mutect2, varscan2
- NEBL | c.2732G>A p.S911N | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV65802135; called by muse, mutect2, varscan2
- NEFH | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs549970192, COSV60216142; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57216110; called by muse, mutect2, varscan2
- NEMF | c.1974+2T>C p.X658_splice | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV53590155; called by muse, mutect2, varscan2
- NEURL4 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59757531; called by muse, mutect2, varscan2
- NFATC2IP | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57909984; called by muse, mutect2, varscan2
- NIPBL | c.5809-1G>T p.X1937_splice | Splice Site (SNP) | VAF 43/123 reads (35%) | catalogued as COSV56947341; called by muse, varscan2
- NLGN3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704838, COSV62442137; called by muse, mutect2, varscan2
- NLK | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV69407889; called by muse, mutect2, varscan2
- NMRAL1 | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.394); catalogued as rs755189854, COSV52059531; called by muse, mutect2, varscan2
- NNT | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759786744, COSV52923915, COSV52925313; called by muse, mutect2, varscan2
- NOP2 | c.1292G>A p.R431Q (on ENST00000322166 / NM_001258308.2; = p.R427Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763509029, COSV59109925; called by muse, mutect2, varscan2
- NOP9 | c.950+2T>C p.X317_splice | Splice Site (SNP) | VAF 61/199 reads (31%) | catalogued as COSV51865162; called by muse, mutect2
- NPBWR1 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100488344; called by muse, mutect2, varscan2
- NPR1 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV64117417; called by muse, mutect2, varscan2
- NPTX2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756274665, COSV55716314; called by muse, mutect2, varscan2
- NPY5R | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 76/249 reads (31%) | catalogued as rs772425843, COSV58451434, COSV58452386; called by muse, mutect2, varscan2
- NR1D1 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as rs200928699, COSV52841735; called by muse, mutect2, varscan2
- NR1H2 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53800384; called by muse, mutect2, varscan2
- NRAP | c.464A>C p.E155A | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV63489423; called by muse, mutect2, varscan2
- NRG1 | c.814A>G p.K272E (on ENST00000405005 / NM_013964.5; = p.K277E on NM_013956.5) | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV55152874; called by muse, mutect2, varscan2
- NRIP3 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.442); catalogued as COSV58469345; called by muse, mutect2
- NRXN1 | c.3779G>A p.G1260D | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as COSV60491049; called by muse, mutect2, varscan2
- NSL1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748993262, COSV65325040; called by muse, mutect2, varscan2
- NT5DC2 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs751375576, COSV58734005; called by muse, mutect2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 68/260 reads (26%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP155 | c.2732T>C p.V911A (on ENST00000231498 / NM_153485.3; = p.V852A on NM_004298.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV51528429; called by muse, mutect2, varscan2
- NUP160 | c.2507T>A p.I836K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV65853944; called by muse, mutect2, varscan2
- NUP214 | c.1947A>G p.G649= | Splice Region (SNP) | VAF 41/121 reads (34%) | catalogued as COSV63908480; called by muse, mutect2, varscan2
- NUP43 | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61189209; called by muse, mutect2, varscan2
- OR10G8 | c.73del p.L25Sfs*22 | Frame Shift Del (DEL) | VAF 54/191 reads (28%) | catalogued as rs1383077583; called by mutect2, pindel, varscan2
- OR10K1 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV56871299; called by muse, mutect2, varscan2
- OR2L2 | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs1266416562, COSV63550563, COSV63562056; called by muse, mutect2, varscan2
- OR2T6 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs182818153, COSV63215979; called by muse, mutect2, varscan2
- OR4D11 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100506668, COSV57585156; called by muse, mutect2, varscan2
- OR4N5 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 125/359 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1453879782, COSV61320327; called by muse, mutect2, varscan2
- OR4X2 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs1203423470, COSV56582851; called by muse, mutect2
- OR51L1 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as rs375372249; called by muse, mutect2, varscan2
- OR51S1 | c.875C>A p.P292Q | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59057882; called by muse, mutect2, varscan2
- OR52E8 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66205570; called by muse, mutect2, varscan2
- OR5D13 | c.884G>T p.R295M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62333235; called by muse, mutect2, varscan2
- OR6C74 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV59605987; called by muse, mutect2, varscan2
- OR8B4 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.216); catalogued as COSV62069529; called by muse, mutect2
- ORC5 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99857498; called by muse, mutect2, varscan2
- OSBPL10 | c.1078T>G p.S360A | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV67337747; called by muse, mutect2, varscan2
- OSER1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs2232289; called by muse, mutect2, varscan2
- P2RY2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs756233719, COSV60775725; called by muse, mutect2, varscan2
- P3H3 | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51831792; called by muse, mutect2
- P3H4 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV58635916; called by muse, mutect2, varscan2
- P4HA1 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368140626, COSV54960231; called by muse, mutect2, varscan2
- P4HTM | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV59086357; called by muse, varscan2
- P4HTM | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV59086373; called by muse, mutect2, varscan2
- PACS1 | c.2137T>C p.Y713H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57697103; called by muse, mutect2
- PADI2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs187842443; called by muse, mutect2, varscan2
- PAFAH1B1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV68210122; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 63/236 reads (27%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAPOLG | c.17+1G>A p.X6_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV53181912; called by muse, mutect2, varscan2
- PARD3B | c.2263G>A p.A755T (on ENST00000406610 / NM_001302769.2; = p.A693T on NM_152526.6) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62506785; called by muse, mutect2, varscan2
- PARP3 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.597); catalogued as COSV51753620; called by muse, mutect2, varscan2
- PAX6 | c.1033-1G>A p.X345_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53792565, COSV53795338; called by muse, mutect2, varscan2
- PCDH15 | c.4961T>C p.L1654S (on ENST00000644397 / NM_001354429.2; = p.L1596S on NM_001142771.2) | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV64670154; called by muse, mutect2, varscan2
- PCDH19 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55260086; called by muse, mutect2, varscan2
- PCDH9 | c.1502del p.N501Mfs*24 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | catalogued as COSV60564880; called by mutect2, pindel, varscan2
- PCDHB11 | c.2309T>C p.V770A | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV61310599; called by muse, mutect2, varscan2
- PCDHB3 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV50567219; called by muse, mutect2, varscan2
- PCDHB9 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.331); catalogued as COSV53376085; called by muse, mutect2, varscan2
- PCDHGA12 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs751785850, COSV52744973, COSV52747242; called by muse, mutect2, varscan2
- PCDHGB4 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV53920655; called by muse, mutect2, varscan2
- PCED1B | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs112959993, COSV71395039; called by muse, mutect2, varscan2
- PCSK5 | c.12del p.S5Afs*58 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as COSV65095270; called by mutect2, pindel, varscan2
- PDE3B | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56381625; called by muse, mutect2, varscan2
- PDGFC | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV56847050; called by muse, mutect2, varscan2
- PDIA3 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55855289; called by muse, mutect2, varscan2
- PEG3 | c.2533A>G p.R845G | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55629370; called by muse, mutect2, varscan2
- PEX5 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV56953880; called by muse, mutect2, varscan2
- PGBD1 | c.593del p.N198Tfs*7 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs749589486; called by mutect2, pindel, varscan2
- PGGHG | c.1540A>G p.S514G | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV101164769; called by muse, mutect2, varscan2
- PGR | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV54798727; called by muse, mutect2, varscan2
- PHF10 | c.1448del p.P483Qfs*? | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs754137375; called by mutect2, pindel, varscan2
- PHIP | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs536256008, COSV51502888; called by muse, mutect2, varscan2
- PHYHIP | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1208497885, COSV58688279; called by muse, mutect2
- PHYKPL | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs781248682, COSV57423454; called by muse, mutect2, varscan2
- PIAS2 | c.1796G>T p.S599I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.094); catalogued as COSV67093993; called by muse, mutect2, varscan2
- PIK3CG | c.989del p.T330Rfs*54 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | catalogued as COSV63247451; called by mutect2, pindel, varscan2
- PIK3R2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55847346; called by muse, mutect2, varscan2
- PIK3R5 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775810359, COSV52652004; called by muse, mutect2, varscan2
- PIKFYVE | c.3835G>A p.V1279I | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV52239043; called by muse, mutect2, varscan2
- PITPNM3 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs950339689, COSV52594362; called by muse, mutect2, varscan2
- PKD1 | c.10619-2A>G p.X3540_splice (on ENST00000262304 / NM_001009944.3; = p.X3539_splice on NM_000296.4) | Splice Site (SNP) | VAF 7/11 reads (64%) | catalogued as CS076657, COSV51913410; called by muse, mutect2, varscan2
- PKD2L1 | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV58395266; called by muse, mutect2, varscan2
- PKDREJ | c.2210T>A p.L737H | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53547739; called by muse, mutect2, varscan2
- PKHD1L1 | c.9856A>G p.T3286A | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as COSV65740273; called by muse, mutect2, varscan2
- PLAAT5 | c.575G>A p.C192Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs1418106336, COSV57136604; called by muse, mutect2, varscan2
- PLCB1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs142186851, COSV62059381; called by muse, mutect2, varscan2
- PLEKHA5 | c.2354-1G>T p.X785_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54697273; called by muse, mutect2, varscan2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLEKHH2 | c.3393A>G p.I1131M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV56751444; called by muse, mutect2, varscan2
- PLIN3 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs577339133, COSV55734652; called by muse, mutect2, varscan2
- PLOD1 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs1163257543, COSV52142567; called by muse, mutect2, varscan2
- PLOD3 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361548571, COSV56181955; called by muse, mutect2, varscan2
- PLXNA1 | c.2522A>G p.H841R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1470423475, COSV52524161; called by muse, mutect2, varscan2
- PLXNA1 | c.4336A>G p.T1446A | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.202); catalogued as COSV52524174; called by muse, mutect2, varscan2
- PLXNB3 | c.5426A>T p.K1809I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62796384, COSV62800796; called by muse, mutect2, varscan2
- PMS2 | c.1239del p.D414Tfs*34 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as CD040607; called by mutect2, varscan2
- PNISR | c.787T>A p.L263M | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV65079091; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- PNPLA7 | c.425del p.N142Tfs*63 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | catalogued as COSV53007520; called by mutect2, pindel, varscan2
- POGK | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs772385405, COSV63311390; called by muse, mutect2, varscan2
- POP1 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV62892279; called by muse, mutect2
- POP1 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 49/180 reads (27%) | catalogued as rs770043633, COSV62892284; called by muse, mutect2, varscan2
- PPIG | c.1363A>G p.R455G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV53642120; called by muse, mutect2
- PPL | c.3951G>T p.E1317D | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV52166981, COSV52169408; called by muse, mutect2, varscan2
- PPP1R10 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs993241542, COSV64738800; called by muse, mutect2
- PPP1R16A | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV52952679; called by muse, mutect2, varscan2
- PPP2R3B | c.928T>A p.F310I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV66812909; called by muse, mutect2, varscan2
- PPP2R5D | c.858-2A>G p.X286_splice | Splice Site (SNP) | VAF 45/182 reads (25%) | catalogued as COSV55150422; called by muse, mutect2, varscan2
- PPP3CC | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs138834215; called by muse, mutect2, varscan2
- PPP5C | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1253543852, COSV50139532, COSV99183738; called by muse, mutect2, varscan2
- PRAG1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV58159376; called by muse, mutect2, varscan2
- PRB2 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 128/440 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV66982676; called by muse, varscan2
- PRDM5 | c.29T>C p.F10S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV53357993; called by muse, mutect2
- PRDX2 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV56877580; called by muse, mutect2
- PRR5L | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61120811; called by muse, mutect2, varscan2
- PRTN3 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.592); catalogued as COSV52255303; called by muse, mutect2
- PRUNE2 | c.9251T>C p.L3084P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56315174; called by muse, mutect2, varscan2
- PSD4 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV55525505; called by muse, mutect2, varscan2
- PSG2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 159/448 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV61544877; called by muse, mutect2, varscan2
- PTBP3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as rs1197956270, COSV57581557; called by muse, mutect2, varscan2
- PTCHD1 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1387152319, COSV65059574; called by muse, mutect2, varscan2
- PTCRA | c.164del p.P55Lfs*113 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | catalogued as COSV58975439; called by mutect2, pindel, varscan2
- PTGDR | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs199553417, COSV60093424; called by muse, mutect2, varscan2
- PTK6 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV53916259; called by muse, mutect2, varscan2
- PTK7 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57847479; called by muse, mutect2, varscan2
- PTPRS | c.4043C>T p.T1348I | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53614866; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- PUM1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1158133157, COSV57083489; called by muse, mutect2, varscan2
- PXDN | c.2927A>G p.H976R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV53230069; called by muse, mutect2, varscan2
- PXDN | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs1341335102, COSV53230079; called by muse, mutect2, varscan2
- PYHIN1 | c.364A>C p.S122R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV63721935; called by muse, mutect2, varscan2
- QSOX2 | c.1221A>G p.I407M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV62393753; called by muse, mutect2, varscan2
- QTRT1 | c.949T>C p.C317R | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51550719; called by muse, mutect2
- R3HCC1L | c.2332A>G p.K778E (on ENST00000612478 / NM_001256619.2; = p.K764E on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV53255908; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV100234622; called by mutect2, varscan2
- RAB27B | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772473656, COSV50494544; called by muse, mutect2, varscan2
- RABEP1 | c.528+2T>C p.X176_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV52584073; called by muse, mutect2, varscan2
- RBBP4 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV65132270; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBL1 | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV60329129; called by muse, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM33 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV56630654; called by muse, mutect2, varscan2
- RBM42 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1383755998, COSV52897141; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as COSV56484832; called by mutect2, varscan2
- RCBTB2 | c.926+2T>C p.X309_splice | Splice Site (SNP) | VAF 43/118 reads (36%) | catalogued as COSV60649580; called by muse, mutect2, varscan2
- RELA | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58014242; called by muse, mutect2, varscan2
- RELB | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55509231; called by muse, mutect2, varscan2
- RELB | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as COSV55509239; called by muse, varscan2
- RET | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs761596036, COSV104412377, COSV60690288; called by muse, mutect2, varscan2
- RFPL1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV62977591; called by muse, mutect2, varscan2
- RFT1 | c.709T>G p.W237G | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV56248483; called by muse, mutect2, varscan2
- RFX6 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 28/107 reads (26%) | catalogued as COSV60584190; called by muse, mutect2, varscan2
- RGS12 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV58750106; called by muse, mutect2, varscan2
- RGS22 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867442961, COSV62659716; called by muse, mutect2, varscan2
- RHOF | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551990941, COSV57362862, COSV57363640; called by muse, mutect2, varscan2
- RHOJ | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779493646, COSV57457542; called by muse, mutect2, varscan2
- RIMKLA | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760622156, COSV69815274; called by muse, mutect2, varscan2
- RIMKLA | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV68909711; called by muse, mutect2, varscan2
- RIMS1 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.346); catalogued as rs1475617034, COSV53448134, COSV53478020; called by muse, mutect2, varscan2
- RLBP1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.937); catalogued as rs1238365040, COSV51527407; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 32/46 reads (70%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF144A | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.424); catalogued as COSV100306213; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 66/126 reads (52%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV71392788; called by muse, mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RPH3A | c.1015T>C p.Y339H (on ENST00000389385 / NM_001143854.2; = p.Y335H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.191); catalogued as COSV66992148; called by muse, mutect2
791 further variants in this file (422 protein-altering or splice-affecting, 341 silent, 28 other) are not listed here.
